Somatic mutation profile of tumor specimen TCGA-CM-5861-01A (aliquot TCGA-CM-5861-01A-01D-1650-10) from TCGA case TCGA-CM-5861, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.7 years (23,253 days).
Specimen TCGA-CM-5861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 752b1621-1d9a-4ff4-8566-10fbe1a4aff3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5861-10A (Blood Derived Normal), aliquot TCGA-CM-5861-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/251ad4bb-8100-49a5-a2cc-9436ddef27d9

The open-access MAF lists 1,698 somatic variants for this specimen: 1,295 protein-altering or splice-affecting, 372 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 947, Silent 372, Frame Shift Del 208, Frame Shift Ins 59, Splice Site 31, Nonsense Mutation 27, Intron 17, Splice Region 15, RNA 9, In Frame Del 6, 3'UTR 3, Translation Start Site 2.

Variants (750 of 1,698; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4338dup p.P1447Tfs*22 | Frame Shift Ins (INS) | VAF 36/80 reads (45%) | catalogued as rs781126037; ClinVar: pathogenic; called by mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 34/87 reads (39%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 20/166 reads (12%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 33/118 reads (28%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCNO | c.248_252del p.L83Rfs*51 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as rs587777498; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CLDN16 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs765256758, CM015915, COSV53228629, COSV99290296; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- FOXN1 | c.1247del p.P416Qfs*134 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs1567886959; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNQ2 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs118192200, CM076249, COSV60431547; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS1 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as rs200905486, CM016007, COSV100799833, COSV62289502; ClinVar: likely pathogenic; called by muse, varscan2
- SLC22A5 | c.844del p.R282Dfs*14 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as rs386134209, CM045438; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.3376A>C p.N1126H | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.637); catalogued as COSV55285096; called by muse, mutect2, varscan2
- AATK | c.1009C>T p.P337S (on ENST00000326724 / NM_001080395.3; = p.P234S on NM_004920.2) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58684944; called by muse, mutect2, varscan2
- ABCA1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as rs1345374392, COSV66063496; called by muse, mutect2, varscan2
- ABCA9 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 45/114 reads (39%) | catalogued as rs1372122909, COSV60619911; called by muse, mutect2, varscan2
- ABCB11 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs1479054328, COSV55584734; called by muse, mutect2, varscan2
- ABL2 | c.1535dup p.K513* (on ENST00000502732 / NM_007314.4; = p.K498* on NM_005158.5) | Frame Shift Ins (INS) | VAF 287/608 reads (47%) | catalogued as rs753365868; called by mutect2, pindel, varscan2
- AC011455.2 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV99671462; called by muse, mutect2
- AC136428.1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 80/320 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV101434979; called by muse, mutect2, varscan2
- ACIN1 | c.3085A>G p.K1029E | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52972866; called by muse, mutect2, varscan2
- ACSL3 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1233889614, COSV62480600; called by muse, mutect2, varscan2
- ADAM11 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52344109; called by muse, mutect2, varscan2
- ADAM2 | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 46/565 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV55858466, COSV55862264; called by muse, mutect2
- ADAM8 | c.1880A>C p.Q627P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV101291702; called by muse, mutect2
- ADAMTS2 | c.2842G>A p.D948N | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.04); catalogued as rs758419331, COSV52363448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS4 | c.2264G>T p.G755V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63489255, COSV63490967; called by muse, mutect2, varscan2
- ADAMTS7 | c.2590del p.L864Wfs*93 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | catalogued as rs1309405734, COSV66307015; called by mutect2, pindel, varscan2
- ADAMTSL1 | c.4258A>G p.I1420V | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101000517; called by muse, mutect2
- ADCY2 | c.2274C>A p.N758K | Missense Mutation (SNP) | VAF 115/373 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV57857380; called by muse, mutect2, varscan2
- ADCY8 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV53895109; called by muse, mutect2, varscan2
- ADCY8 | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV99653450; called by muse, varscan2
- ADGRB3 | c.3862A>G p.N1288D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.049); catalogued as rs539620519, COSV53233413; called by muse, mutect2, varscan2
- ADGRL1 | c.834G>T p.W278C (on ENST00000340736 / NM_001008701.3; = p.W273C on NM_014921.5) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61563495; called by muse, mutect2, varscan2
- ADGRV1 | c.2825C>A p.P942H | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67977747; called by muse, mutect2, varscan2
- ADGRV1 | c.10430A>G p.D3477G | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV67977755; called by muse, mutect2, varscan2
- ADH6 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99422683; called by muse, mutect2, varscan2
- AFF4 | c.207A>C p.R69S | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV54791144; called by muse, mutect2, varscan2
- AFM | c.1147A>G p.N383D | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56918882; called by muse, mutect2, varscan2
- AFTPH | c.2545G>A p.D849N (on ENST00000238855 / NM_203437.3; = p.D821N on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53215634; called by muse, mutect2, varscan2
- AGPAT5 | c.870-1G>T p.X290_splice | Splice Site (SNP) | VAF 33/136 reads (24%) | catalogued as COSV99576598; called by muse, mutect2, varscan2
- AGTPBP1 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1326331925, COSV100429349, COSV100430015; called by muse, varscan2
- AHNAK2 | c.12131G>T p.G4044V | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60906778; called by muse, mutect2, varscan2
- AKAP9 | c.10322G>A p.R3441H (on ENST00000359028; = p.R3417H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs770556341, COSV62337987; called by muse, mutect2, varscan2
- AKR1B10 | c.388A>T p.N130Y | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV62054857; called by muse, mutect2, varscan2
- ALPK2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs763980190, COSV64489989; called by muse, varscan2
- AMBRA1 | c.2422C>T p.R808C (on ENST00000458649 / NM_001367468.1; = p.R718C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54047977; called by muse, mutect2, varscan2
- AMIGO3 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.338); catalogued as rs1435513430, COSV57537424; called by muse, mutect2, varscan2
- ANGPTL2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs367678181; called by muse, mutect2, varscan2
- ANKFY1 | c.2072del p.P691Rfs*61 (on ENST00000341657 / NM_001330063.2; = p.P692Rfs*61 on NM_016376.5) | Frame Shift Del (DEL) | VAF 29/86 reads (34%) | catalogued as COSV58920130; called by mutect2, varscan2
- ANKRD35 | c.1507T>C p.W503R | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841812; called by muse, mutect2
- ANKRD52 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.41); catalogued as rs1207415272, COSV57281962; called by muse, mutect2, varscan2
- ANO5 | c.2412C>T p.C804= | Splice Region (SNP) | VAF 32/82 reads (39%) | catalogued as rs756578795, COSV61081674; called by muse, mutect2, varscan2
- ANTXR1 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV58008458; called by muse, mutect2, varscan2
- ANXA11 | c.282dup p.S95Lfs*102 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs759677084; called by mutect2, pindel
- AP1G2 | c.2069del p.N690Tfs*6 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs34487488; called by mutect2, pindel, varscan2
- AP5S1 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV55693586; called by muse, mutect2
- APBA1 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.945); catalogued as rs371567762; called by muse, mutect2, varscan2
- APC | c.130A>G p.M44V | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs1424437002, COSV57322322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEX2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66623727; called by muse, mutect2, varscan2
- APOB | c.6641A>G p.E2214G | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as CD141900; called by muse, mutect2, varscan2
- APOB | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766083346, COSV51921966; called by muse, mutect2, varscan2
- APOBEC3C | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV99329095; called by muse, mutect2, varscan2
- APOBEC3G | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs368187496; called by muse, mutect2, varscan2
- APOF | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs758037147, COSV58476286; called by muse, varscan2
- APOL3 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 38/98 reads (39%) | PolyPhen benign (0.001); catalogued as COSV62579059; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as rs749401724; called by mutect2, varscan2
- ARF4 | c.261T>C p.G87= | Splice Region (SNP) | VAF 39/109 reads (36%) | catalogued as COSV100327233; called by muse, varscan2
- ARHGAP21 | c.3697C>T p.P1233S | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57601731; called by muse, mutect2, varscan2
- ARHGAP26 | c.1994del p.P665Rfs*135 | Frame Shift Del (DEL) | VAF 58/163 reads (36%) | catalogued as rs1298538973; called by mutect2, pindel, varscan2
- ARHGAP28 | c.1685C>T p.A562V (on ENST00000383472 / NM_001366230.1; = p.A403V on NM_001010000.3) | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs759071148, COSV51630860; called by muse, mutect2, varscan2
- ARHGAP31 | c.4064C>A p.P1355H | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51788709; called by muse, mutect2, varscan2
- ARHGAP33 | c.2546G>A p.R849K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as COSV50138857, COSV99139253; called by muse, mutect2, varscan2
- ARHGAP36 | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV52263550; called by muse, mutect2, varscan2
- ARHGAP44 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1218875900, COSV52388683; called by muse, mutect2, varscan2
- ARHGEF10 | c.3529G>A p.G1177S (on ENST00000398564; = p.G1152S on NM_014629.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV100035144; called by muse, mutect2, varscan2
- ARHGEF11 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 87/129 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347868807, COSV63810156; called by muse, mutect2, varscan2
- ARHGEF15 | c.1949dup p.V651Rfs*18 | Frame Shift Ins (INS) | VAF 14/33 reads (42%) | catalogued as rs752138065; called by mutect2, varscan2
- ARID4B | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 92/1516 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs917178689, COSV99936034; called by muse, mutect2
- ARID5A | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773876068, COSV62590678; called by muse, mutect2, varscan2
- ARL16 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs753996726, COSV61269022; called by muse, mutect2, varscan2
- ARMC5 | c.2249T>G p.L750R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51654567; called by muse, mutect2
- ARRDC3 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54364380; called by muse, mutect2, varscan2
- ASAP3 | c.1114T>C p.Y372H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60872816; called by muse, mutect2, varscan2
- ASB14 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762743268, COSV55699478; called by muse, mutect2, varscan2
- ASGR2 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54689184; called by muse, mutect2, varscan2
- ASPG | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV71933511; called by muse, mutect2
- ASPH | c.1391A>G p.Y464C | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101064216; called by muse, varscan2
- ASPN | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV65015794; called by muse, mutect2, varscan2
- ATAD2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs750708802, COSV54876942, COSV54880175; called by muse, mutect2, varscan2
- ATG10 | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 53/215 reads (25%) | catalogued as COSV56422167; called by muse, mutect2, varscan2
- ATG2A | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65965747; called by muse, mutect2, varscan2
- ATG2B | c.5591T>C p.V1864A | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1419515138, COSV55889286; called by muse, varscan2
- ATG4A | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV58963991; called by muse, mutect2, varscan2
- ATG4B | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as rs771274919, COSV60349168; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | catalogued as rs770350293; called by mutect2, pindel, varscan2
- ATM | c.6009T>A p.D2003E | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV53724090; called by muse, mutect2, varscan2
- ATP10A | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs146387652; called by mutect2, varscan2
- ATP11B | c.3463G>A p.A1155T | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV60025768; called by muse, mutect2, varscan2
- ATP1A4 | c.2239G>A p.V747I | Missense Mutation (SNP) | VAF 197/330 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs767194862, COSV63625346; called by muse, mutect2, varscan2
- ATP6V0A1 | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231377; called by muse, varscan2
- ATP6V0B | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV52542476; called by muse, mutect2, varscan2
- ATP7A | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV58441902; called by muse, mutect2, varscan2
- ATP8B2 | c.148C>T p.R50W (on ENST00000672630; = p.R17W on NM_001005855.2) | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1424511928, COSV59244486; called by muse, mutect2, varscan2
- ATPSCKMT | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, mutect2, varscan2
- ATRX | c.7181T>C p.V2394A | Missense Mutation (SNP) | VAF 151/425 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV64870820; called by muse, mutect2, varscan2
- ATXN2L | c.2978C>G p.P993R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100294865; called by muse, mutect2, varscan2
- ATXN3L | c.586T>A p.L196I | Missense Mutation (SNP) | VAF 156/427 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as COSV66075193; called by mutect2, varscan2
- AUTS2 | c.1034C>A p.P345H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); catalogued as COSV61381554; called by muse, mutect2, varscan2
- AVL9 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.416); catalogued as COSV59463747; called by muse, mutect2, varscan2
- AVPR2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1557100783, COSV61685742; called by muse, mutect2, varscan2
- B3GNT9 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1363845215, COSV54625387; called by muse, mutect2, varscan2
- BAHCC1 | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as COSV57022377; called by muse, mutect2, varscan2
- BAHCC1 | c.2662del p.H888Tfs*86 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs782623998; called by mutect2, pindel, varscan2
- BANF1 | c.14A>C p.Q5P | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV56463247; called by muse, varscan2
- BAX | c.569_571del p.K190del | In Frame Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs748073277; called by pindel, varscan2
- BAZ1A | c.4226del p.R1409Kfs*11 | Frame Shift Del (DEL) | VAF 235/758 reads (31%) | catalogued as COSV62408820; called by mutect2, pindel, varscan2
- BCHE | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52253110; called by muse, mutect2, varscan2
- BCL2A1 | c.420+2T>C p.X140_splice | Splice Site (SNP) | VAF 50/357 reads (14%) | catalogued as COSV51212841; called by muse, mutect2, varscan2
- BCL2L1 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV100304789; called by muse, mutect2, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs756382429; called by pindel, varscan2
- BCL9L | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52681762; called by muse, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BDH1 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.115); catalogued as COSV64017632; called by muse, mutect2, varscan2
- BICC1 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV65855787; called by muse, mutect2, varscan2
- BIRC2 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV57160534; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs112825485, COSV63243821; called by muse, mutect2, varscan2
- BMP15 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.854); catalogued as rs371418883, CM092909, COSV53139787; called by muse, mutect2, varscan2
- BNC2 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.253); catalogued as COSV66148244; called by muse, mutect2
- BORCS7 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs748603513, COSV54915456; called by muse, mutect2, varscan2
- BRCA2 | c.472T>C p.S158P | Missense Mutation (SNP) | VAF 145/383 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs113114005, COSV66447708; called by muse, mutect2, varscan2
- BRD4 | c.1729A>G p.N577D | Missense Mutation (SNP) | VAF 417/1214 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.146); catalogued as COSV54581799; called by muse, mutect2, varscan2
- BTN3A3 | c.1478A>G p.E493G | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55070736; called by muse, mutect2, varscan2
- BTNL3 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); catalogued as rs771112486, COSV61564247; called by muse, mutect2, varscan2
- BTNL9 | c.35A>T p.K12M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.167); catalogued as COSV59793195; called by muse, mutect2
- C10orf71 | c.1050del p.C351Afs*48 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as COSV60509047; called by mutect2, pindel, varscan2
- C11orf80 | c.1541A>G p.K514R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100690858, COSV60927823; called by muse, mutect2, varscan2
- C11orf87 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV59355944; called by muse, mutect2, varscan2
- C12orf29 | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs750066464, COSV58348251; called by muse, mutect2, varscan2
- C19orf44 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as COSV55609885; called by muse, mutect2, varscan2
- C4orf50 | c.679G>A p.G227R (on ENST00000324058; = p.G1459R on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs115887613, COSV60689147; called by muse, mutect2, varscan2
- C9 | c.1588T>C p.C530R | Missense Mutation (SNP) | VAF 140/377 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54674002; called by muse, mutect2
- C9 | c.877del p.M293Cfs*5 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as rs777158966; called by mutect2, pindel, varscan2
- CA3 | c.33C>T p.N11= | Splice Region (SNP) | VAF 10/53 reads (19%) | catalogued as rs1302075406, COSV53409133, COSV53411365; called by muse, mutect2, varscan2
- CABP4 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57796970; called by muse, mutect2, varscan2
- CACNA1B | c.4312G>A p.A1438T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99498776; called by muse, mutect2, varscan2
- CACNA1C | c.6352G>T p.G2118W (on ENST00000399634 / NM_001167625.1; = p.G2047W on NM_000719.7) | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV100220830; called by muse, mutect2, varscan2
- CACNA1E | c.1961T>G p.L654R | Missense Mutation (SNP) | VAF 58/528 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62381210; called by muse, mutect2
- CACNA1H | c.5272C>A p.L1758I | Missense Mutation (SNP) | VAF 144/399 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52352469; called by muse, mutect2, varscan2
- CACNA1I | c.1010C>A p.A337D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60800389; called by muse, mutect2, varscan2
- CACNA2D1 | c.2941T>C p.Y981H (on ENST00000356253 / NM_001366867.1; = p.Y969H on NM_000722.4) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1257558222, COSV62371688; called by muse, mutect2, varscan2
- CAPN3 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349313665, CM052831, CM119415, COSV58818997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD16 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 128/370 reads (35%) | catalogued as COSV65212658; called by muse, mutect2, varscan2
- CARD9 | c.953G>T p.C318F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59996180; called by muse, mutect2, varscan2
- CASP10 | c.903A>C p.Q301H (on ENST00000272879 / NM_032974.5; = p.Q258H on NM_001230.5) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV53776523; called by muse, mutect2
- CBLN2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs1281951081, COSV54050115; called by muse, mutect2, varscan2
- CCDC158 | c.2664+2T>C p.X888_splice | Splice Site (SNP) | VAF 41/103 reads (40%) | catalogued as COSV66355087; called by muse, mutect2, varscan2
- CCDC57 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs770033906, COSV66432204; called by muse, mutect2, varscan2
- CCDC61 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs768189086, COSV50516397; called by muse, mutect2, varscan2
- CCDC85A | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs753500740, COSV68147276; called by muse, mutect2, varscan2
- CCDC88C | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs770066487, COSV66233787; called by muse, mutect2, varscan2
- CCKAR | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200911163, COSV55159618; called by muse, mutect2, varscan2
- CCL14 | c.79C>T p.R27W (on ENST00000618404 / NM_032963.4; = p.Q27* on NM_032962.4) | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.82); catalogued as rs186783049; called by muse, mutect2, varscan2
- CCN4 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV51529198; called by muse, mutect2, varscan2
- CCNB1 | c.804C>G p.D268E | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV56509084; called by muse, mutect2, varscan2
- CCNDBP1 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53039948; called by muse, mutect2, varscan2
- CCNYL1 | c.529G>C p.V177L (on ENST00000295414 / NM_001330218.2; = p.V107L on NM_152523.2) | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV54938898; called by muse, varscan2
- CCSER2 | c.2422A>G p.T808A | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56501000; called by muse, mutect2, varscan2
- CCT5 | c.1400G>A p.G467D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54723108; called by mutect2, varscan2
- CD1B | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 63/345 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs960498473, COSV63803732; called by muse, mutect2, varscan2
- CD248 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60935673; called by muse, mutect2, varscan2
- CD5L | c.614A>T p.Q205L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as COSV63820997, COSV63822829; called by muse, mutect2, varscan2
- CDC20B | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV57049404; called by muse, mutect2, varscan2
- CDC37 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV55767175; called by muse, mutect2, varscan2
- CDH16 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.164); catalogued as COSV55334598; called by muse, mutect2, varscan2
- CDH8 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100184164, COSV54845802, COSV54859074; called by muse, mutect2, varscan2
- CDHR1 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as COSV60559329; called by muse, mutect2, varscan2
- CDK12 | c.1607del p.P536Hfs*74 | Frame Shift Del (DEL) | VAF 78/254 reads (31%) | catalogued as COSV71002430; called by mutect2, pindel, varscan2
- CDKL3 | c.1772del p.F591Sfs*9 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | catalogued as rs753494539; called by mutect2, varscan2
- CDKL5 | c.702G>T p.Q234H | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.998); catalogued as COSV66110089; called by muse, mutect2, varscan2
- CDS2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.022); catalogued as rs1459774853, COSV66895197; called by muse, mutect2, varscan2
- CELSR1 | c.4323G>T p.E1441D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV53082905; called by muse, mutect2, varscan2
- CENPC | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 127/374 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as COSV56621097; called by muse, mutect2, varscan2
- CENPF | c.2885T>G p.I962S | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV65272417; called by muse, mutect2, varscan2
- CEP170B | c.4016C>T p.A1339V (on ENST00000453495; = p.A1268V on NM_015005.3) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV52043714; called by muse, mutect2, varscan2
- CEP70 | c.465+2T>C p.X155_splice | Splice Site (SNP) | VAF 46/370 reads (12%) | catalogued as COSV99389431; called by muse, mutect2, varscan2
- CERT1 | c.1837G>A p.A613T (on ENST00000405807 / NM_001130105.1; = p.A485T on NM_005713.3) | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV54655126; called by muse, mutect2, varscan2
- CES3 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375395231, COSV57592579; called by muse, mutect2, varscan2
- CFAP410 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1402134765, COSV57394097; called by muse, mutect2
- CFAP43 | c.4637A>G p.Q1546R | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as COSV100829429; called by muse, mutect2
- CFAP45 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs1313378938, COSV100928648; called by muse, mutect2
- CGA | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63644042; called by muse, mutect2, varscan2
- CGB1 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100031725; called by muse, mutect2, varscan2
- CHAF1A | c.2255T>C p.V752A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.421); catalogued as COSV100011364; called by muse, mutect2, varscan2
- CHAT | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60319659; called by muse, mutect2, varscan2
- CHEK1 | c.297del p.D99Efs*2 | Frame Shift Del (DEL) | VAF 78/246 reads (32%) | catalogued as COSV54021997; called by mutect2, pindel, varscan2
- CHRFAM7A | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 208/1602 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100241670; called by muse, varscan2
- CHRND | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs142531974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST11 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1232266665, COSV57984257, COSV57993760; called by muse, varscan2
- CIAO3 | c.823+2T>C p.X275_splice | Splice Site (SNP) | VAF 32/90 reads (36%) | catalogued as COSV52400579; called by muse, mutect2
- CIC | c.3800G>A p.S1267N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as rs978945814, COSV50646408; called by muse, varscan2
- CKMT2 | c.1102T>C p.Y368H | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV54172102; called by muse, mutect2, varscan2
- CLCN2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99658802; called by muse, mutect2, varscan2
- CLCN4 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV66464966; called by muse, mutect2, varscan2
- CLEC4G | c.746A>T p.H249L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV61002787; called by muse, mutect2, varscan2
- CLIC3 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65406306; called by muse, mutect2, varscan2
- CLN3 | c.1157C>T p.A386V (on ENST00000360019 / NM_001286104.2; = p.A410V on NM_000086.2) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs369801432; called by muse, mutect2, varscan2
- CLOCK | c.875G>T p.R292M | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59400270; called by muse, mutect2
- CLRN3 | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV64098111, COSV64098369; called by muse, mutect2, varscan2
- CLSTN2 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as COSV71717723; called by muse, mutect2, varscan2
- CMC2 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as rs781067998, COSV54728712; called by muse, mutect2, varscan2
- CMIP | c.2276T>C p.L759P (on ENST00000537098 / NM_198390.2; = p.L665P on NM_030629.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67696994; called by muse, mutect2, varscan2
- CMTM3 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs201311207, COSV62680046; called by muse, mutect2, varscan2
- CNBD2 | c.542T>G p.L181R | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62586272; called by muse, mutect2
- CNOT1 | c.2429G>A p.G810D | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV57763651; called by muse, varscan2
- CNOT1 | c.2333T>C p.V778A | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57763662; called by muse, varscan2
- CNOT2 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1161007517, COSV57500539; called by muse, mutect2, varscan2
- CNST | c.1494G>T p.Q498H | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.518); catalogued as COSV63621421; called by muse, mutect2, varscan2
- CNTNAP1 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs775036363, COSV52847724; called by muse, mutect2, varscan2
- COL12A1 | c.5929T>C p.S1977P | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV59388769; called by muse, mutect2, varscan2
- COL14A1 | c.4251G>A p.M1417I | Missense Mutation (SNP) | VAF 121/567 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV52846508; called by muse, mutect2, varscan2
- COL20A1 | c.1679dup p.R561Efs*168 | Frame Shift Ins (INS) | VAF 28/62 reads (45%) | catalogued as rs761988638; called by mutect2, varscan2
- COL27A1 | c.2124+2T>C p.X708_splice | Splice Site (SNP) | VAF 62/145 reads (43%) | catalogued as rs760476125, COSV61924268; called by muse, mutect2, varscan2
- COL5A3 | c.3391C>A p.Q1131K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.834); catalogued as COSV53405409; called by muse, mutect2, varscan2
- COL6A3 | c.7765+2T>C p.X2589_splice | Splice Site (SNP) | VAF 21/63 reads (33%) | catalogued as COSV55078737, COSV55090556; called by muse, mutect2, varscan2
- COL6A6 | c.5636A>G p.H1879R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV62016923; called by muse, mutect2
- CORO6 | c.991T>C p.C331R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100801389; called by muse, mutect2
- CORO7 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.272); catalogued as rs775838457, COSV52027708; called by muse, mutect2, varscan2
- CPA5 | c.1093T>C p.Y365H | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62568604; called by muse, mutect2, varscan2
- CPS1 | c.1327T>C p.Y443H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51801055; called by muse, mutect2, varscan2
- CPSF1 | c.4315G>A p.V1439I | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs1554861915, COSV58232045; called by muse, mutect2, varscan2
- CREB3L3 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99314375; called by muse, mutect2
- CRHR2 | c.229C>A p.R77= | Splice Region (SNP) | VAF 14/60 reads (23%) | catalogued as COSV59263573; called by muse, mutect2, varscan2
- CSMD1 | c.4208G>A p.R1403H (on ENST00000520002; = p.R1402H on NM_033225.6) | Missense Mutation (SNP) | VAF 221/392 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758153692, COSV59277963; called by muse, mutect2, varscan2
- CSMD1 | c.3176G>A p.G1059D (on ENST00000520002; = p.G1058D on NM_033225.6) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59277987, COSV59353066; called by muse, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 56/135 reads (41%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSRNP1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs149009984, COSV56187051; called by muse, mutect2, varscan2
- CTBP1 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1290217261, COSV52071633; called by muse, mutect2, varscan2
- CTSF | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768809245, COSV59747277; called by muse, mutect2, varscan2
- CUX1 | c.749C>T p.A250V (on ENST00000292535 / NM_181552.4; = p.A261V on NM_001913.5) | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.59); catalogued as rs1029919361, COSV52889997; called by muse, varscan2
- CYB561D1 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs755258039, COSV60203828; called by muse, mutect2, varscan2
- CYP11B1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as COSV52824654, COSV52830972; called by muse, mutect2, varscan2
- D2HGDH | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV58318910; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs751187768; called by mutect2, varscan2
- DBT | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV64494916; called by muse, mutect2, varscan2
- DBT | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV64494918; called by muse, mutect2, varscan2
- DCC | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 108/260 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100498270, COSV59081935; called by muse, varscan2
- DDX1 | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 88/674 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); catalogued as COSV51837788; called by muse, varscan2
- DERA | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1056220724, COSV70773605; called by muse, mutect2, varscan2
- DFFB | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.6); catalogued as COSV100138747; called by muse, mutect2, varscan2
- DGKK | c.2143A>G p.S715G | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.423); catalogued as COSV101053140; called by muse, mutect2, varscan2
- DGKK | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1569544298, COSV101053141; called by muse, mutect2, varscan2
- DHX16 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1273530977, COSV64579712; called by muse, mutect2, varscan2
- DHX34 | c.2375T>C p.L792P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.877); catalogued as COSV60894298; called by muse, mutect2
- DIO3 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63774442; called by muse, mutect2, varscan2
- DIP2A | c.1565C>T p.T522M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1047774685, COSV59471091; called by muse, mutect2, varscan2
- DISC1 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV54399732; called by muse, mutect2, varscan2
- DISC1 | c.1015del p.D339Tfs*4 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | catalogued as CM107408, COSV54413570, COSV99698668; called by mutect2, pindel, varscan2
- DISP3 | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV53819658; called by muse, mutect2, varscan2
- DKC1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs782117503, COSV65729099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP2 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 30/102 reads (29%) | catalogued as COSV70093557; called by muse, mutect2, varscan2
- DLGAP3 | c.2195A>G p.H732R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.958); catalogued as COSV99332991; called by muse, mutect2
- DMD | c.8939C>T p.A2980V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV58889689, COSV58945477; called by muse, mutect2, varscan2
- DMD | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 110/352 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55851693; called by muse, mutect2, varscan2
- DNAAF1 | c.1058A>G p.E353G | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57576276; called by muse, mutect2, varscan2
- DNAAF2 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100024213; called by muse, mutect2, varscan2
- DNAH17 | c.7312C>T p.R2438C | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs769324928, COSV67749293; called by muse, mutect2, varscan2
- DNAH3 | c.7159G>A p.V2387M | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.182); catalogued as rs772302598, COSV54501646; called by muse, mutect2, varscan2
- DNAH5 | c.7474G>A p.A2492T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54202086, COSV54222629, COSV54234650; called by muse, mutect2, varscan2
- DNAH9 | c.7280A>T p.K2427M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52332249, COSV52347707, COSV99307837; called by muse, mutect2, varscan2
- DNAI2 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758997612, COSV56756577; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAI2 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV56756609; called by muse, mutect2, varscan2
- DNASE1L2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs931672724, COSV57037495; called by muse, mutect2
- DNMT1 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV61576300; called by muse, mutect2, varscan2
- DOP1B | c.3455del p.G1152Afs*25 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs764554714; called by mutect2, pindel, varscan2
- DPP3 | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV64755768; called by muse, mutect2
- DPP6 | c.2006G>T p.G669V (on ENST00000377770 / NM_001364500.2; = p.G607V on NM_001936.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100127088, COSV59634123; called by muse, mutect2, varscan2
- DRD5 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100431951; called by muse, mutect2
- DSC1 | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV57141333; called by muse, mutect2, varscan2
- DSPP | c.211A>G p.N71D | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV99217727; called by muse, mutect2, varscan2
- DSPP | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.982); catalogued as COSV99217730; called by muse, mutect2, varscan2
- DST | c.12647C>T p.A4216V (on ENST00000361203 / NM_001374722.1; = p.A1804V on NM_015548.5) | Missense Mutation (SNP) | VAF 167/562 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1484781372, COSV54995978; called by muse, mutect2, varscan2
- DST | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1563465064, COSV56797404; called by muse, mutect2, varscan2
- DTNBP1 | c.784_788del p.E262Hfs*10 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs773202322; called by pindel, varscan2
- DUSP12 | c.998T>C p.L333S | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV63411049; called by muse, mutect2
- DUSP8 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as COSV59029253; called by muse, mutect2, varscan2
- DUXA | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 126/370 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748002224, COSV101617126, COSV73729482; called by muse, varscan2
- DVL1 | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs748535372, COSV100229719; called by muse, mutect2, varscan2
- DYNC1I2 | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs769156663, COSV55524148; called by muse, mutect2, varscan2
- DZANK1 | c.1852del p.E618Kfs*6 (on ENST00000262547 / NM_001099407.1; = p.E425Kfs*6 on NM_018152.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as COSV52756070; called by mutect2, pindel, varscan2
- E2F8 | c.1066+2T>C p.X356_splice | Splice Site (SNP) | VAF 84/204 reads (41%) | catalogued as COSV51466512; called by muse, varscan2
- ECT2 | c.684+2T>C p.X228_splice (on ENST00000392692 / NM_001349098.2; = p.X197_splice on NM_018098.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 59/158 reads (37%) | catalogued as rs765273363, COSV51686175; called by muse, mutect2, varscan2
- EDA2R | c.180T>G p.S60R | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV53631099, COSV99490844; called by muse, mutect2, varscan2
- EEFSEC | c.966A>G p.I322M | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54619413; called by muse, mutect2, varscan2
- EFHB | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV55544494; called by muse, mutect2, varscan2
- EGR2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as COSV54346059; called by muse, mutect2, varscan2
- EIF1 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV60422124; called by muse, mutect2, varscan2
- EIF2B4 | c.631G>T p.G211C (on ENST00000347454 / NM_001034116.2; = p.G210C on NM_015636.3) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM152531, COSV99277826; called by muse, mutect2
- ELANE | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs140642538, CM097554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELMO2 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51681127; called by muse, mutect2, varscan2
- ELOVL5 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58648523; called by muse, mutect2, varscan2
- EMP3 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99507438; called by muse, mutect2, varscan2
- EMX2 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV71294350; called by muse, varscan2
- ENDOG | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV63508731; called by muse, mutect2, varscan2
- ENPP1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV62929845; called by muse, mutect2, varscan2
- EPHB2 | c.1765+2T>C p.X589_splice (on ENST00000400191 / NM_001309193.2; = p.X590_splice on NM_004442.7) | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV65859628; called by muse, mutect2, varscan2
- EPN1 | c.1642T>C p.Y548H (on ENST00000270460 / NM_001321263.1; = p.Y522H on NM_013333.3) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV50035745; called by muse, mutect2, varscan2
- ESR1 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.174); catalogued as COSV52781090, COSV52802732; called by muse, mutect2, varscan2
- ETV5 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60499591; called by muse, mutect2, varscan2
- EVI2B | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 260/671 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV58363275; called by muse, mutect2, varscan2
- EVPL | c.4207C>T p.R1403C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764730730, COSV56906980; called by muse, mutect2, varscan2
- EXO1 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV62216165; called by muse, mutect2, varscan2
- EXO1 | c.2352G>T p.K784N | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV62216172; called by muse, mutect2, varscan2
- F2R | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 123/321 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59928194; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 26/125 reads (21%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM126A | c.688A>T p.I230L | Missense Mutation (SNP) | VAF 72/367 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV69471082; called by muse, mutect2, varscan2
- FAM167A | c.234dup p.Q79Afs*40 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs1252762581; called by mutect2, varscan2
- FAM20C | c.715T>C p.Y239H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58231961; called by muse, mutect2, varscan2
- FAM47A | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.923); catalogued as rs45577239, COSV60493971, COSV99080504; called by muse, mutect2, varscan2
- FAM47A | c.449T>G p.L150R | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60493739; called by muse, mutect2
- FAM71C | c.408dup p.Q137Tfs*24 | Frame Shift Ins (INS) | VAF 52/160 reads (33%) | catalogued as rs762930877; called by mutect2, varscan2
- FAR2 | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as COSV51723001; called by muse, mutect2, varscan2
- FARSA | c.1264T>C p.Y422H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100108975; called by muse, mutect2, varscan2
- FASN | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs963388974, COSV60750217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 40/289 reads (14%) | catalogued as rs773607911, COSV52947201; called by mutect2, pindel, varscan2
- FBN1 | c.8500A>G p.T2834A | Missense Mutation (SNP) | VAF 71/590 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1284038548, COSV57308438; called by muse, mutect2, varscan2
- FBXL16 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV100179083; called by muse, mutect2, varscan2
- FBXO6 | c.512T>C p.F171S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV52415222; called by muse, varscan2
- FBXW10 | c.2467C>T p.Q823* | Nonsense Mutation (SNP) | VAF 40/286 reads (14%) | catalogued as COSV57059095; called by muse, mutect2, varscan2
- FCRL2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as rs144041840; called by muse, mutect2, varscan2
- FGF23 | c.586del p.R196Gfs*4 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as COSV52975661; called by mutect2, pindel
- FIG4 | c.2222C>T p.T741M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1274229885, COSV57791213; ClinVar: uncertain significance; called by muse, varscan2
- FILIP1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.134); catalogued as COSV99385653; called by muse, mutect2, varscan2
- FKBP15 | c.1663T>C p.S555P | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs1279717445, COSV53031701; called by muse, mutect2, varscan2
- FLNC | c.4303G>A p.V1435M | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs370643162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.7411del p.H2471Tfs*58 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | catalogued as COSV57959687; called by mutect2, pindel, varscan2
- FMN2 | c.3841G>T p.G1281W | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV60415470; called by muse, mutect2, varscan2
- FMR1NB | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV100975598, COSV65070959; called by muse, mutect2, varscan2
- FO393400.1 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.591); catalogued as COSV99640764; called by muse, mutect2
- FOLR3 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100281827; called by muse, mutect2, varscan2
- FOXK1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1054767933, COSV61064216; called by muse, mutect2, varscan2
- FOXL2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57725380; called by muse, mutect2, varscan2
- FOXP3 | c.943A>G p.S315G | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.162); catalogued as rs1569529656, COSV100873218; called by muse, mutect2, varscan2
- FOXR2 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59257724; called by muse, mutect2, varscan2
- FPR3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV59328099; called by muse, mutect2, varscan2
- FRAS1 | c.10926A>C p.R3642S | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV53586758; called by muse, mutect2, varscan2
- FRMPD4 | c.3323A>G p.E1108G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.164); catalogued as COSV66210972; called by muse, mutect2, varscan2
- FRY | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs772100301, COSV66564575; called by muse, mutect2, varscan2
- FRY | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779292401, COSV66564585; called by muse, mutect2, varscan2
- FSCN2 | c.625T>G p.C209G | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100603310; called by muse, mutect2
- FSCN3 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.081); catalogued as rs376914564, COSV50000121; called by muse, mutect2, varscan2
- FSIP2 | c.19781G>A p.R6594H | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765693370, COSV100555803; called by muse, varscan2
- FXR2 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100007256; called by muse, mutect2
- GAA | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56406639; called by muse, mutect2, varscan2
- GABRB1 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99782721; called by muse, mutect2, varscan2
- GAL3ST2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs763705984, COSV51949324; called by muse, mutect2, varscan2
- GALNT17 | c.485A>C p.N162T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61146037; called by muse, mutect2, varscan2
- GALNT2 | c.830A>G p.N277S | Missense Mutation (SNP) | VAF 162/820 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.332); catalogued as COSV64192701; called by muse, mutect2, varscan2
- GASK1B | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV56704196; called by muse, mutect2, varscan2
- GASK1B | c.170G>T p.R57M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV56704226; called by muse, mutect2, varscan2
- GATA3 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1436692613, COSV100651141; called by muse, mutect2, varscan2
- GDF5 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs780244059, COSV100976920, COSV65499591; called by muse, varscan2
- GGT5 | c.452A>G p.H151R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99571754; called by muse, mutect2, varscan2
- GHDC | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as rs1252159909, COSV100054528, COSV56987155; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP8 | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 34/102 reads (33%) | catalogued as rs746795576; called by mutect2, varscan2
- GIPC1 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV52874344; called by muse, mutect2, varscan2
- GJA8 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs142026480, CM146420, COSV53787651; called by muse, mutect2, varscan2
- GLB1L2 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1327001125, COSV100335437; called by muse, mutect2, varscan2
- GLRA2 | c.1315A>T p.I439F | Missense Mutation (SNP) | VAF 113/435 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.218); catalogued as COSV54335534; called by muse, mutect2, varscan2
- GLRA4 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs746558748, COSV101009505, COSV65455041; called by muse, mutect2, varscan2
- GML | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55278815; called by muse, mutect2, varscan2
- GNAI3 | c.461+2T>C p.X154_splice | Splice Site (SNP) | VAF 60/145 reads (41%) | catalogued as COSV63983242; called by muse, mutect2, varscan2
- GNE | c.533G>A p.R178K (on ENST00000396594 / NM_001128227.3; = p.R147K on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64951200; called by muse, mutect2, varscan2
- GNL1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV64920639; called by muse, mutect2, varscan2
- GOLGA2 | c.2929dup p.Y977Lfs*4 | Frame Shift Ins (INS) | VAF 36/130 reads (28%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLGA5 | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs780447151, COSV50831944; called by muse, mutect2, varscan2
- GP1BA | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.53); catalogued as rs755360664, COSV56698552; called by muse, mutect2, varscan2
- GP2 | c.1276C>T p.R426C (on ENST00000381362 / NM_001007240.3; = p.R423C on NM_001502.4) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); catalogued as rs201001285, COSV56891908; called by muse, mutect2, varscan2
- GPHN | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 58/156 reads (37%) | catalogued as COSV59472210; called by muse, mutect2, varscan2
- GPN2 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV64651519; called by muse, mutect2, varscan2
- GPR137B | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63990646; called by muse, mutect2, varscan2
- GPR149 | c.1714A>G p.T572A | Missense Mutation (SNP) | VAF 200/528 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101078619; called by muse, mutect2, varscan2
- GPR149 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67665559, COSV67665931; called by muse, mutect2, varscan2
- GPR19 | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60122858; called by muse, mutect2, varscan2
- GPR75 | c.382T>C p.F128L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV61824467; called by muse, mutect2, varscan2
- GPRASP2 | c.983C>G p.S328C | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs777172000, COSV59990163; called by muse, mutect2, varscan2
- GPSM2 | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV99915478; called by muse, mutect2, varscan2
- GRID1 | c.2711A>T p.E904V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV100025456; called by muse, mutect2
- GRIK5 | c.724T>C p.Y242H | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99491128; called by muse, mutect2, varscan2
- GRIK5 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs1025783902, COSV99491129; called by mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | catalogued as rs747773579; called by mutect2, varscan2
- GSTM5 | c.603C>G p.S201R | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV56656471; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1667A>G p.D556G | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV99735121; called by muse, mutect2, varscan2
- GUCA1A | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as COSV50003419; called by muse, mutect2, varscan2
- GUCY1A1 | c.377-2A>G p.X126_splice | Splice Site (SNP) | VAF 52/147 reads (35%) | catalogued as COSV56648740; called by muse, mutect2
- GUF1 | c.799A>G p.R267G | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55781329; called by muse, mutect2, varscan2
- GXYLT1 | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as COSV99788849; called by mutect2, varscan2
- H1-4 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1289737443, COSV56799651; called by muse, mutect2, varscan2
- H2AC20 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 101/530 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV58611208; called by muse, mutect2, varscan2
- H2BC5 | c.132G>T p.K44N | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as rs779615788, COSV56799658; called by muse, mutect2, varscan2
- HADHB | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 216/590 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs768738452, CM140307, COSV58544359; called by muse, mutect2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 19/29 reads (66%) | catalogued as rs747918697; called by mutect2, varscan2
- HCFC1 | c.5975G>A p.G1992D | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60069157; called by muse, mutect2, varscan2
- HCLS1 | c.566-1G>A p.X189_splice | Splice Site (SNP) | VAF 84/233 reads (36%) | catalogued as COSV58854131; called by muse, mutect2, varscan2
- HCRTR2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.077); catalogued as rs1406582957, COSV63793509; called by muse, mutect2, varscan2
- HDAC11 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs749223823, COSV55472255, COSV99849809; called by muse, mutect2, varscan2
- HDAC4 | c.2703dup p.M902Hfs*5 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | catalogued as rs747537946; called by mutect2, varscan2
- HDAC4 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 36/151 reads (24%) | catalogued as COSV61858674; called by muse, mutect2, varscan2
- HDAC9 | c.1865C>A p.A622E | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV67765974; called by muse, mutect2, varscan2
- HDGF | c.521A>C p.N174T | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100625848; called by muse, mutect2
- HDLBP | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 124/396 reads (31%) | catalogued as COSV60491695; called by muse, mutect2, varscan2
- HDX | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 228/600 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52972409; called by muse, mutect2, varscan2
- HECTD4 | c.4934T>C p.V1645A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66386286; called by mutect2, varscan2
- HECW1 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.001); catalogued as rs1323812313, COSV67820911; called by mutect2, varscan2
- HELZ2 | c.4936G>A p.A1646T (on ENST00000467148 / NM_001037335.2; = p.A1077T on NM_033405.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.229); catalogued as COSV71295285; called by muse, mutect2, varscan2
- HEPH | c.2957T>C p.V986A (on ENST00000343002; = p.V719A on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV57958515; called by muse, mutect2, varscan2
- HEXB | c.1445T>C p.I482T | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs773007352, COSV54666771; called by muse, mutect2, varscan2
- HIF3A | c.298C>T p.L100F (on ENST00000377670 / NM_152795.4; = p.L98F on NM_152794.4) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52195528; called by muse, mutect2, varscan2
- HIP1 | c.1696T>C p.W566R | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61182997; called by muse, mutect2
- HIPK2 | c.1338G>A p.W446* | Nonsense Mutation (SNP) | VAF 30/83 reads (36%) | catalogued as COSV61225299; called by muse, mutect2, varscan2
- HIPK4 | c.1424T>C p.L475P | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.916); catalogued as COSV99396911; called by muse, mutect2, varscan2
- HMCN1 | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 73/391 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54874168; called by muse, mutect2, varscan2
- HNRNPA1 | c.372T>G p.Y124* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV52935360; called by muse, mutect2, varscan2
- HNRNPAB | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 48/133 reads (36%) | catalogued as COSV57422742; called by muse, mutect2, varscan2
- HNRNPD | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100003025; called by muse, mutect2
- HOXD13 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66832271; called by muse, mutect2, varscan2
- HOXD9 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV50890486; called by muse, mutect2, varscan2
- HP | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63325594; called by muse, mutect2, varscan2
- HPCA | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs774794783, COSV100992215, COSV65102640; called by muse, mutect2, varscan2
- HR | c.635G>T p.S212I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57190446; called by muse, mutect2
- HS3ST3A1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.165); catalogued as rs1416026947, COSV52372510; called by muse, mutect2, varscan2
- HSPG2 | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101012973; called by muse, mutect2, varscan2
- HTR3A | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as rs528818878, COSV55467802; called by muse, mutect2, varscan2
- HTRA1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.938); catalogued as rs1565422018, COSV64563261; called by muse, mutect2, varscan2
- IDO1 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs1212415937, COSV53712786; called by muse, mutect2, varscan2
- IFI16 | c.1698A>C p.E566D (on ENST00000295809 / NM_001364867.2; = p.E510D on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as rs777391755, COSV55530534; called by muse, mutect2
- IFI35 | c.148del p.L50Wfs*17 | Frame Shift Del (DEL) | VAF 54/151 reads (36%) | catalogued as COSV55896797, COSV99887721; called by mutect2, pindel, varscan2
- IFT140 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs545083874, COSV68485724; called by muse, mutect2, varscan2
- IGDCC3 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV100031379, COSV60079131; called by muse, mutect2, varscan2
- IGDCC4 | c.2613del p.T872Qfs*11 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as COSV61539288; called by mutect2, pindel, varscan2
- IGFBP3 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as rs768974204, COSV51871859; called by muse, mutect2, varscan2
- IGSF10 | c.5987A>G p.Y1996C | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99185786; called by muse, mutect2, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 37/127 reads (29%) | catalogued as rs748943611; called by mutect2, varscan2
- IHO1 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368444069; called by muse, mutect2, varscan2
- IKZF4 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs761622543, COSV56266554; called by muse, mutect2, varscan2
- IL11 | c.509del p.G170Afs*14 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs1362559161; called by mutect2, varscan2
- IL31RA | c.1853T>C p.V618A | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.121); catalogued as COSV61692281; called by muse, mutect2, varscan2
- ILDR1 | c.1357del p.R453Gfs*127 (on ENST00000344209 / NM_001199799.2; = p.R409Gfs*127 on NM_175924.4) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs759967990; called by mutect2, pindel
- ILF3 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200955896, COSV51553785; called by muse, mutect2, varscan2
- INF2 | c.1936A>G p.K646E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53029371; called by muse, mutect2, varscan2
- INMT | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV50000041; called by muse, mutect2, varscan2
- INPP5F | c.2114T>C p.F705S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100740293; called by muse, mutect2, varscan2
- INSYN2A | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV54728636; called by muse, mutect2
- INTS5 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs371125173; called by muse, mutect2, varscan2
- IPO4 | c.1649T>G p.V550G | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV99938176; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1621G>A p.D541N (on ENST00000485419 / NM_001197113.1; = p.D465N on NM_014575.3) | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61838201; called by muse, mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 54/162 reads (33%) | catalogued as rs780982673; called by mutect2, varscan2
- ISLR | c.1264T>C p.F422L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs762159204, COSV51432859; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV56441625; called by muse, mutect2
- ITGA10 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs974284591, COSV65195880; called by muse, mutect2, varscan2
- ITGA7 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs150476577, COSV57691303; called by muse, mutect2, varscan2
- ITGAV | c.1228T>C p.S410P | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53708912; called by muse, mutect2, varscan2
- ITIH1 | c.2294G>T p.R765M | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV56251795; called by muse, mutect2, varscan2
- ITPKB | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as rs764431826, COSV55256766, COSV55261999; called by muse, mutect2, varscan2
- ITPR1 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); catalogued as COSV56966743; called by muse, mutect2
- ITPR3 | c.7522G>A p.V2508M | Missense Mutation (SNP) | VAF 121/400 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65267701; called by muse, varscan2
- ITPR3 | c.7561G>A p.A2521T | Missense Mutation (SNP) | VAF 144/339 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65267705; called by muse, varscan2
- JCAD | c.1515del p.D507Mfs*23 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs770240166; called by mutect2, pindel, varscan2
- KANK1 | c.4007G>T p.R1336M | Missense Mutation (SNP) | VAF 117/305 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66527208; called by muse, mutect2, varscan2
- KANSL1 | c.2209T>C p.S737P | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99294762; called by muse, mutect2, varscan2
- KATNB1 | c.1583C>A p.A528D | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65548664; called by muse, mutect2, varscan2
- KCNA3 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63900852; called by muse, mutect2, varscan2
- KCNA4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1268762688, COSV60250389; called by muse, mutect2, varscan2
- KCNB2 | c.2632A>G p.S878G | Missense Mutation (SNP) | VAF 118/218 reads (54%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs373156197; called by muse, mutect2
- KCNC2 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371497523, COSV54361561; called by muse, mutect2, varscan2
- KCNE4 | c.265T>C p.Y89H | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56053963; called by muse, mutect2, varscan2
- KCNJ10 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100927940; called by muse, mutect2
- KCNJ8 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53715126; called by muse, mutect2, varscan2
- KCNJ9 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 162/249 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV63631413; called by muse, mutect2, varscan2
- KCNK7 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100442318; called by muse, mutect2, varscan2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 30/176 reads (17%) | catalogued as rs753256170; called by mutect2, varscan2
- KCTD19 | c.62dup p.W22Lfs*43 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs769207794; called by mutect2, pindel, varscan2
- KDM5C | c.4260G>A p.W1420* | Nonsense Mutation (SNP) | VAF 63/159 reads (40%) | catalogued as COSV100949365; called by muse, mutect2, varscan2
- KIF16B | c.231+2T>C p.X77_splice | Splice Site (SNP) | VAF 33/104 reads (32%) | catalogued as COSV61700815; called by muse, mutect2, varscan2
- KIF21B | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59751995; called by muse, mutect2, varscan2
- KLF8 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV63847113; called by muse, mutect2, varscan2
- KLHDC8B | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs756090460, COSV100234274; called by mutect2, varscan2
- KLHL22 | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs201252029, COSV61019517; called by muse, mutect2, varscan2
- KLHL7 | c.1647T>A p.N549K (on ENST00000339077 / NM_001031710.3; = p.N501K on NM_018846.5) | Missense Mutation (SNP) | VAF 36/709 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV59159531; called by muse, mutect2
- KMT2B | c.4543T>C p.Y1515H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.052); catalogued as COSV55856344; called by muse, mutect2, varscan2
- KMT2B | c.7532G>A p.R2511Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1232711537, COSV55819574; called by muse, mutect2, varscan2
- KMT5A | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV57862122; called by muse, mutect2, varscan2
- KMT5B | c.1569A>C p.R523S | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV58563433; called by muse, mutect2
- KNCN | c.361del p.A121Lfs*111 (on ENST00000481882 / NM_001322255.2; = p.A98Lfs*? on NM_001097611.1) | Frame Shift Del (DEL) | VAF 53/196 reads (27%) | catalogued as rs539443691; called by mutect2, pindel, varscan2
- KNDC1 | c.4175A>C p.E1392A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV100465740; called by muse, mutect2
- KNOP1 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 188/508 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV54926513; called by muse, varscan2
- KNTC1 | c.3859G>A p.V1287M | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV61078679, COSV61079652; called by muse, mutect2
- KNTC1 | c.4034C>T p.A1345V | Missense Mutation (SNP) | VAF 116/369 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745930138, COSV61078690; called by muse, mutect2, varscan2
- KPNA3 | c.655A>G p.N219D | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99904290; called by muse, varscan2
- KPNA6 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV65359150; called by muse, mutect2, varscan2
- KRT85 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs1186787135, COSV57735840; called by muse, mutect2, varscan2
- KRT85 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); catalogued as rs1397367244, COSV57735848; called by muse, mutect2, varscan2
- KRTAP3-1 | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.191); catalogued as rs753535111, COSV101196089; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs770565486; called by pindel, varscan2
- L3MBTL3 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as rs763375416, COSV62384072; called by muse, mutect2, varscan2
- LAMB1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs756177392, COSV55961305; called by muse, mutect2, varscan2
- LAMB3 | c.1790T>A p.L597Q | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV61915091; called by muse, mutect2, varscan2
- LARP4B | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs138081905; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 69/230 reads (30%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LAX1 | c.178A>G p.N60D | Missense Mutation (SNP) | VAF 136/680 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as COSV65848733; called by muse, mutect2, varscan2
- LCN8 | c.148A>G p.T50A (on ENST00000612714 / NM_001345934.1; = p.T27A on NM_178469.3) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV60209228; called by muse, mutect2, varscan2
- LCTL | c.788A>T p.D263V | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV58421450; called by muse, mutect2, varscan2
- LDHAL6B | c.641_642del p.L214Rfs*18 | Frame Shift Del (DEL) | VAF 35/133 reads (26%) | catalogued as COSV55682143; called by mutect2, pindel, varscan2
- LGR5 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV57001841; called by muse, mutect2, varscan2
- LHX1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as rs1333689590; called by muse, mutect2, varscan2
- LHX2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs749130254, COSV65317738; called by muse, mutect2
- LIAS | c.467T>C p.L156P (on ENST00000261434 / NM_001363700.2; = p.L259P on NM_006859.4) | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54694605; called by muse, varscan2
- LILRA5 | c.685A>C p.S229R | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100007024; called by muse, mutect2
- LILRB3 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1282125367; called by muse, mutect2, varscan2
- LIMD2 | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs367901623; called by muse, mutect2, varscan2
- LLGL2 | c.694-1G>A p.X232_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | catalogued as COSV51341751; called by muse, mutect2, varscan2
- LONP2 | c.1809C>G p.H603Q | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53520144; called by muse, mutect2, varscan2
- LONRF2 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV66539166; called by muse, mutect2, varscan2
- LPA | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); catalogued as rs757112211, COSV60295974; called by muse, mutect2
- LRBA | c.3388C>A p.Q1130K | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.006); catalogued as COSV63949336; called by muse, mutect2, varscan2
- LRFN3 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1415252731, COSV55816803; called by muse, mutect2, varscan2
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 52/226 reads (23%) | catalogued as COSV100540885; called by mutect2, varscan2
- LRGUK | c.1975dup p.T659Nfs*26 | Frame Shift Ins (INS) | VAF 24/59 reads (41%) | catalogued as rs1382711421; called by mutect2, varscan2
- LRP1 | c.8175G>T p.E2725D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.322); catalogued as COSV54501251; called by muse, mutect2, varscan2
- LRP1B | c.6753A>G p.I2251M | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67183150; called by muse, mutect2, varscan2
- LRP2 | c.12873G>T p.K4291N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as rs771595990, COSV99789630; called by muse, mutect2, varscan2
- LRRC36 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1369139057, COSV100326217; called by muse, mutect2, varscan2
- LRRC40 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63938121; called by muse, mutect2, varscan2
- LRRC45 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV60710315; called by muse, mutect2, varscan2
- LRRC4C | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV99539093; called by muse, mutect2, varscan2
- LRRN1 | c.1705A>C p.T569P | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.719); catalogued as COSV60012153; called by mutect2, varscan2
- LYST | c.7628-1G>A p.X2543_splice | Splice Site (SNP) | VAF 76/140 reads (54%) | catalogued as rs764555650, COSV101090012; called by muse, mutect2
- LZTS1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as rs759562008, COSV99743163; called by muse, mutect2, varscan2
- LZTS3 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs959144924, COSV100232345; called by muse, mutect2, varscan2
- MACF1 | c.1327T>C p.C443R | Missense Mutation (SNP) | VAF 86/268 reads (32%) | catalogued as COSV58358033; called by muse, mutect2
- MAG | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs142036180; called by muse, mutect2, varscan2
- MAGEC3 | c.502del p.E168Rfs*45 | Frame Shift Del (DEL) | VAF 55/203 reads (27%) | catalogued as rs1295601131; called by mutect2, pindel, varscan2
- MAGI3 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56827313; called by muse, mutect2, varscan2
- MAN1B1 | c.1014del p.L339Sfs*2 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | catalogued as rs752359237; called by mutect2, varscan2
- MAP3K11 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs201727045, COSV58418152; called by muse, mutect2, varscan2
- MAP3K14 | c.2626C>T p.R876W | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as COSV100077475; called by muse, mutect2, varscan2
- MAP3K21 | c.2143del p.Q715Rfs*236 | Frame Shift Del (DEL) | VAF 57/103 reads (55%) | catalogued as rs1375324580, COSV64042370; called by mutect2, pindel, varscan2
- MAPK8IP3 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as COSV51715661, COSV51722670; called by muse, mutect2, varscan2
- MAPRE3 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51866165; called by muse, mutect2, varscan2
- MASP2 | c.1973T>C p.M658T | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99534387; called by muse, mutect2, varscan2
- MAU2 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.808); catalogued as COSV53233473; called by muse, varscan2
- MCC | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); catalogued as rs370355557; called by muse, mutect2, varscan2
- MCM6 | c.1077T>C p.H359= | Splice Region (SNP) | VAF 35/172 reads (20%) | catalogued as COSV99919277; called by muse, mutect2
- MCM8 | c.789+2T>C p.X263_splice | Splice Site (SNP) | VAF 55/168 reads (33%) | catalogued as COSV54509930; called by muse, mutect2, varscan2
- MDM2 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV50697814; called by muse, mutect2, varscan2
- MED16 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs760147614, COSV99516047; called by muse, varscan2
- MEGF6 | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374246247; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs745891632; called by mutect2, varscan2
- MFAP3L | c.617A>T p.K206M | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64371723; called by muse, mutect2, varscan2
- MGA | c.8581C>T p.R2861W (on ENST00000219905 / NM_001164273.1; = p.R2652W on NM_001080541.2) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs749267770, COSV54948011; called by muse, mutect2, varscan2
- MICAL3 | c.5393A>G p.D1798G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV71588028; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 30/55 reads (55%) | catalogued as rs765803753; called by mutect2, pindel
- MICU1 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV63143155; called by muse, mutect2, varscan2
- MIF4GD | c.575A>G p.Q192R (on ENST00000325102 / NM_001370592.1; = p.Q226R on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557030914, COSV99821684; called by muse, mutect2
- MKI67 | c.3749C>T p.P1250L | Missense Mutation (SNP) | VAF 29/457 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.258); catalogued as COSV100896850; called by muse, mutect2
- MKRN3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs777034398, COSV58808435, COSV58809349; called by muse, mutect2, varscan2
- MLIP | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as rs369010969; called by muse, mutect2, varscan2
- MNDA | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 89/487 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63739788; called by muse, mutect2, varscan2
- MOCS1 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV57933314; called by muse, varscan2
- MOXD1 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60941598, COSV60941925; called by muse, mutect2, varscan2
- MPPED1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs375787111; called by muse, mutect2, varscan2
- MRE11 | c.1098+2T>A p.X366_splice | Splice Site (SNP) | VAF 104/349 reads (30%) | catalogued as COSV60573490; called by muse, mutect2, varscan2
- MROH2B | c.3757G>A p.A1253T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as rs976737031, COSV68180747; called by muse, mutect2, varscan2
- MROH5 | c.1245C>T p.D415= | Splice Region (SNP) | VAF 58/92 reads (63%) | catalogued as rs199540989, COSV101436082; called by muse, mutect2, varscan2
- MRPL14 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs531985422, COSV64394396; called by muse, mutect2, varscan2
- MRPL3 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.102); catalogued as COSV53913263; called by muse, mutect2, varscan2
- MST1R | c.2057T>C p.L686P | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99619312; called by muse, mutect2
- MSX2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754536048, COSV53326379; called by muse, mutect2, varscan2
- MTHFD1L | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1218331603, COSV66223545; called by muse, mutect2, varscan2
- MTMR14 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56003172; called by muse, mutect2, varscan2
- MTRR | c.715G>A p.V239M (on ENST00000264668; = p.V212M on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as COSV52941425; called by muse, mutect2, varscan2
- MTUS2 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV70912600, COSV70915943; called by muse, mutect2, varscan2
- MUC16 | c.38321G>A p.R12774H | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs548938808, COSV67485780; called by muse, mutect2, varscan2
- MUC16 | c.17560A>T p.T5854S | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.071); catalogued as COSV67442201; called by muse, mutect2, varscan2
- MUC20 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs369043659, COSV57846855; called by muse, mutect2, varscan2
- MUS81 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as rs763130846, COSV57258805; called by muse, mutect2, varscan2
- MXRA5 | c.6611G>T p.G2204V | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54222689; called by muse, mutect2, varscan2
- MYCBP2 | c.13323+2T>C p.X4441_splice (on ENST00000357337; = p.X4479_splice on NM_015057.5) | Splice Site (SNP) | VAF 15/51 reads (29%) | catalogued as COSV62009313; called by muse, mutect2, varscan2
- MYG1 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV52932080; called by muse, mutect2, varscan2
- MYH15 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV56303886; called by muse, mutect2
- MYH9 | c.2774A>T p.E925V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV53381635; called by muse, mutect2, varscan2
- MYO18A | c.2822A>C p.N941T | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.619); catalogued as COSV62862071; called by muse, mutect2, varscan2
- MYO1C | c.3188G>T p.R1063L (on ENST00000648651 / NM_001080779.2; = p.R1028L on NM_033375.5) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV62998245; called by muse, mutect2, varscan2
- MYO1C | c.1668C>T p.T556= (on ENST00000648651 / NM_001080779.2; = p.T521= on NM_033375.5) | Splice Region (SNP) | VAF 19/48 reads (40%) | catalogued as rs1401860688, COSV62998252; called by muse, mutect2, varscan2
- MYO3A | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1235170434, COSV56318574; called by muse, mutect2
- MYO9A | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61847220; called by muse, mutect2, varscan2
- MYOM3 | c.3475G>T p.E1159* | Nonsense Mutation (SNP) | VAF 59/171 reads (35%) | catalogued as COSV100141888, COSV58389701; called by muse, mutect2, varscan2
- MYRF | c.1370G>A p.R457Q (on ENST00000278836 / NM_001127392.3; = p.R448Q on NM_013279.4) | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs762223967, COSV53885484; called by muse, mutect2, varscan2
- N4BP2L2 | c.1435A>G p.N479D | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57227188; called by muse, mutect2, varscan2
- NAALADL2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1476423276, COSV101458189; called by muse, mutect2, varscan2
- NAALADL2 | c.2060A>G p.Q687R | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs761316248, COSV71983306; called by muse, mutect2
- NAGA | c.1150A>G p.T384A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV67169710; called by muse, varscan2
- NANOS3 | c.203G>T p.R68L (on ENST00000397555; = p.R87L on NM_001098622.2) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV59248115; called by muse, mutect2, varscan2
- NAT10 | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs868597633, COSV57662216; called by muse, mutect2, varscan2
- NAT14 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99220183; called by muse, mutect2, varscan2
- NAV1 | c.481del p.L161Wfs*33 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | catalogued as rs1346393455; called by mutect2, pindel
- NAV2 | c.7017C>T p.I2339= (on ENST00000396087 / NM_001244963.2; = p.I2280= on NM_145117.5) | Splice Region (SNP) | VAF 14/36 reads (39%) | catalogued as rs763894768, COSV60656191; called by muse, mutect2, varscan2
- NBL1 | c.517del p.H173Tfs*37 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs1382618264; called by mutect2, pindel, varscan2
- NBPF3 | c.1808T>C p.V603A | Missense Mutation (SNP) | VAF 184/538 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV59056408; called by muse, mutect2, varscan2
- NCAPD3 | c.3539T>C p.V1180A | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV73257803; called by muse, mutect2, varscan2
- NCKAP5L | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776524596, COSV100259047; called by muse, mutect2, varscan2
- NCOA4 | c.1244A>T p.E415V | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs782431324; called by muse, mutect2, varscan2
- NELFCD | c.737C>T p.T246M (on ENST00000602795; = p.T228M on NM_198976.4) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1236829853, COSV59744986; called by muse, mutect2, varscan2
- NELL2 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61568224; called by muse, mutect2, varscan2
- NEUROD2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as COSV56910456; called by muse, mutect2, varscan2
- NF1 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs199474739, CM087526, CS1311515, COSV62191947; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / not provided; called by muse, mutect2, varscan2
- NFE2L3 | c.1930_1932del p.D644del | In Frame Del (DEL) | VAF 24/206 reads (12%) | catalogued as rs776567501; called by mutect2, pindel, varscan2
- NFKB2 | c.2072-1G>T p.X691_splice | Splice Site (SNP) | VAF 15/81 reads (19%) | catalogued as COSV50041611; called by muse, mutect2, varscan2
- NHSL2 | c.993G>T p.R331S (on ENST00000510661; = p.R697S on NM_001013627.2) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65452277, COSV65453016; called by muse, mutect2, varscan2
- NID1 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51614435; called by muse, mutect2, varscan2
- NINJ1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64922459; called by muse, mutect2
- NKAPD1 | c.442C>T p.R148C (on ENST00000280352 / NM_001082970.2; = p.R149C on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs370435297, COSV99736526; called by muse, mutect2, varscan2
- NKX2-2 | c.370dup p.D124Gfs*186 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | catalogued as rs752776917, COSV101010588; called by mutect2, varscan2
- NKX6-1 | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.827); catalogued as COSV55683962; called by muse, varscan2
- NLGN3 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.102); catalogued as COSV62441485; called by muse, mutect2, varscan2
- NLGN4X | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 137/378 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52003073; called by muse, mutect2, varscan2
- NLRP13 | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV61619700; called by muse, mutect2
- NOA1 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51735783; called by muse, mutect2, varscan2
- NOD2 | c.2630+2T>C p.X877_splice | Splice Site (SNP) | VAF 80/206 reads (39%) | catalogued as COSV56048094; called by muse, mutect2
- NOL4 | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV52337076; called by muse, mutect2, varscan2
- NOP58 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51895456; called by muse, mutect2, varscan2
- NOS1 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.548); catalogued as COSV57606099; called by muse, mutect2, varscan2
- NOS2 | c.3412_3414del p.K1138del | In Frame Del (DEL) | VAF 21/70 reads (30%) | catalogued as rs768443192; called by pindel, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTUM | c.973T>C p.Y325H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV101293813; called by muse, mutect2, varscan2
- NPHP3 | c.3895G>A p.G1299S | Missense Mutation (SNP) | VAF 206/619 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV99393323; called by muse, varscan2
- NPHS2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100858194; called by muse, mutect2, varscan2
- NPR1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs561449958, COSV64140168; called by muse, mutect2, varscan2
- NPVF | c.206dup p.N69Kfs*4 | Frame Shift Ins (INS) | VAF 65/283 reads (23%) | catalogued as rs766699446; called by mutect2, pindel, varscan2
- NR1H2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV53801061; called by muse, mutect2, varscan2
- NR1I3 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV63467164; called by muse, varscan2
- NRXN1 | c.1793A>G p.Y598C | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58434931, COSV58494221; called by muse, varscan2
- NSUN6 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1453316567, COSV66031580; called by muse, mutect2, varscan2
- NTN5 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1282504723, COSV54306417; called by muse, mutect2, varscan2
- NUAK1 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54600137; called by muse, mutect2
- NUF2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs781627921, COSV54841863; called by muse, mutect2, varscan2
- NUMA1 | c.5356dup p.L1786Pfs*18 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | catalogued as rs1184519643; called by mutect2, pindel, varscan2
- NUP98 | c.5390C>G p.A1797G (on ENST00000359171 / NM_001365126.1; = p.A1780G on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV51708363; called by muse, mutect2, varscan2
- NVL | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 207/341 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55869841; called by muse, mutect2, varscan2
- OBI1 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1303006679, COSV56144334; called by muse, mutect2, varscan2
- OBSCN | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52736812; called by muse, mutect2, varscan2
- OBSCN | c.17800C>A p.P5934T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV52736878; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 14/121 reads (12%) | catalogued as rs762005098; called by mutect2, pindel
- ODF2L | c.1876G>A p.V626I (on ENST00000317336; = p.V610I on NM_020729.3) | Missense Mutation (SNP) | VAF 448/1154 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV54013066; called by muse, mutect2, varscan2
- OGFRL1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV64971646, COSV64972280; called by muse, mutect2, varscan2
- OGN | c.479A>T p.D160V | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV52760243; called by muse, mutect2, varscan2
- OGN | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99364226; called by muse, mutect2, varscan2
- OLFM2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs554951359, COSV53428307; called by muse, mutect2, varscan2
- OPTN | c.76dup p.H26Pfs*37 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs753966040; called by mutect2, varscan2
- OR10J1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs778065154, COSV71128098; called by muse, mutect2, varscan2
- OR10J3 | c.407T>G p.I136S | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV59953455; called by muse, mutect2, varscan2
- OR1C1 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68715333; called by muse, mutect2
- OR1I1 | c.250A>G p.N84D | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV52917228; called by muse, mutect2, varscan2
- OR2AG1 | c.350T>C p.F117S | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV56625182; called by muse, mutect2, varscan2
- OR2B11 | c.4A>G p.K2E | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59509169; called by muse, mutect2, varscan2
- OR5H15 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 102/855 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1305717159, COSV62947294; called by muse, mutect2, varscan2
- OR5L2 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 108/320 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV101004307, COSV65723317; called by muse, mutect2, varscan2
- OR5T2 | c.931A>G p.M311V | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1565082393, COSV57587676; called by muse, mutect2
- OR6X1 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs1275486333, COSV60009263; called by muse, mutect2, varscan2
- OR8K1 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV54401231, COSV54401510; called by muse, mutect2
- ORAI2 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (1); PolyPhen possibly damaging (0.566); catalogued as COSV62689087; called by muse, mutect2
- OSBPL10 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as rs756687024, COSV67335768; called by muse, mutect2
- OSBPL6 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51910268; called by muse, mutect2, varscan2
- P2RX2 | c.1258A>G p.T420A (on ENST00000343948 / NM_170683.4; = p.T322A on NM_012226.5) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.488); catalogued as COSV57673468; called by muse, mutect2, varscan2
- P3H4 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as COSV58634866; called by muse, mutect2, varscan2
- PACSIN3 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1431423793, COSV100096502; called by muse, mutect2
- PAM | c.369A>C p.E123D | Missense Mutation (SNP) | VAF 110/324 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV99173643; called by muse, mutect2
- PAPPA2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.509); catalogued as rs1213081972, COSV62772268; called by muse, mutect2, varscan2
- PARD3 | c.1351T>C p.Y451H | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV60744519; called by muse, mutect2, varscan2
- PARP10 | c.606del p.L204Wfs*38 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs782379603; called by mutect2, pindel, varscan2
- PARP4 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as rs1566021517, COSV67960348; called by muse, mutect2, varscan2
- PAX3 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV51336858; called by muse, mutect2, varscan2
- PBXIP1 | c.1772T>C p.V591A | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV63776755; called by muse, mutect2, varscan2
- PCARE | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV59052826; called by muse, mutect2
- PCDH10 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52086902; called by muse, mutect2, varscan2
- PCDH10 | c.1528A>G p.M510V | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV52086908, COSV52103376; called by muse, mutect2, varscan2
- PCDH18 | c.2878C>A p.Q960K | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs754728442, COSV61266190; called by muse, mutect2, varscan2
- PCDHA6 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782653124, COSV65341551; called by muse, mutect2, varscan2
- PCDHA8 | c.1387T>C p.F463L | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.399); catalogued as rs376542022; called by muse, mutect2, varscan2
- PCDHB10 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53374947; called by muse, mutect2, varscan2
- PCDHB15 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782417963, COSV50858123; called by muse, mutect2
- PCDHB2 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99165985; called by muse, varscan2
- PCDHGA1 | c.797C>G p.A266G | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65294738; called by muse, mutect2, varscan2
- PCDHGA6 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs1436138705, COSV53893908; called by muse, mutect2, varscan2
- PCDHGB3 | c.991T>G p.C331G | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53893893; called by muse, mutect2, varscan2
- PCDHGB7 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.595); catalogued as COSV53893923; called by muse, mutect2, varscan2
- PCDHGC3 | c.1388A>G p.D463G | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.19); catalogued as COSV52742380; called by muse, mutect2, varscan2
- PCLO | c.9716G>A p.R3239H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779385664, COSV61613933; called by muse, mutect2, varscan2
- PCLO | c.4663T>C p.F1555L | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV61613961; called by muse, mutect2, varscan2
- PCNT | c.1693G>T p.G565C | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100855826; called by muse, mutect2, varscan2
- PDE4DIP | c.4928A>G p.D1643G | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs782814417, COSV57672118; called by muse, mutect2, varscan2
- PDIA5 | c.1157del p.P386Rfs*26 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs766425459, COSV60251765; called by mutect2, pindel, varscan2
- PDLIM1 | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1169606503, COSV61473429; called by muse, mutect2
- PDLIM5 | c.1003T>G p.S335A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV58744880; called by muse, mutect2
- PDRG1 | c.358A>G p.N120D | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV52430935; called by muse, mutect2, varscan2
- PEDS1 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV100502148; called by muse, mutect2
- PER1 | c.3277C>A p.H1093N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.113); catalogued as COSV57917156; called by muse, mutect2, varscan2
- PF4 | c.113A>G p.D38G | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as COSV56020459; called by muse, mutect2, varscan2
- PFKFB2 | c.994T>C p.C332R | Missense Mutation (SNP) | VAF 51/296 reads (17%) | PolyPhen probably damaging (0.992); catalogued as COSV65547123; called by muse, mutect2
- PFN2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV53522663; called by muse, mutect2, varscan2
- PFN4 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV57530962; called by muse, mutect2, varscan2
- PGAM1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.437); catalogued as rs559703869, COSV58355288; called by muse, mutect2, varscan2
- PGS1 | c.1266G>T p.K422N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV53143184; called by muse, mutect2, varscan2
- PHACTR1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV60658919; called by muse, mutect2, varscan2
- PHACTR2 | c.1016dup p.L340Sfs*4 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs1338848227; called by mutect2, varscan2
- PHC1 | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.766); catalogued as COSV70417476; called by muse, mutect2
- PHF10 | c.539A>T p.Y180F | Missense Mutation (SNP) | VAF 24/622 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV59324125; called by muse, mutect2
- PHF14 | c.1692A>T p.K564N | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV68854002; called by muse, mutect2
- PHLDA1 | c.1020_1037del p.P341_Q346del | In Frame Del (DEL) | VAF 82/378 reads (22%) | catalogued as rs764264995; called by mutect2, varscan2
- PHLDB1 | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs201439807, COSV61876237; called by muse, mutect2, varscan2
- PIGQ | c.1163T>G p.L388R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50312122; called by muse, mutect2
- PIK3C2A | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV56400123; called by muse, mutect2, varscan2
- PIK3R6 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs377023801; called by muse, mutect2, varscan2
- PINK1 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58630289; called by muse, mutect2, varscan2
- PIP4K2A | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60539828; called by muse, mutect2, varscan2
- PIP5K1A | c.887del p.L296Wfs*25 (on ENST00000368888 / NM_001135638.2; = p.L283Wfs*25 on NM_003557.3) | Frame Shift Del (DEL) | VAF 58/367 reads (16%) | catalogued as rs756244757; called by mutect2, pindel, varscan2
- PITRM1 | c.2938G>A p.G980S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs772171696, COSV56525400; called by mutect2, varscan2
- PKD1 | c.4895T>C p.I1632T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51910031; called by muse, mutect2, varscan2
- PKDREJ | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as COSV99479289; called by muse, varscan2
- PLA2G4F | c.2381A>G p.N794S | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV51825293; called by muse, mutect2, varscan2
- PLA2G6 | c.521A>T p.Y174F | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV59267720; called by muse, mutect2, varscan2
- PLAT | c.1685C>A p.P562Q | Missense Mutation (SNP) | VAF 122/420 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51527505; called by muse, mutect2, varscan2
- PLEC | c.2718C>T p.D906= (on ENST00000322810 / NM_201380.4; = p.D796= on NM_000445.5) | Splice Region (SNP) | VAF 23/114 reads (20%) | catalogued as rs781821809, COSV59600781; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.2389G>A p.A797T (on ENST00000322810 / NM_201380.4; = p.A687T on NM_000445.5) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV59600830; called by muse, varscan2
- PLEC | c.1132G>A p.V378M (on ENST00000322810 / NM_201380.4; = p.V268M on NM_000445.5) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1213427822, COSV59600876; called by muse, mutect2, varscan2
- PLEKHA5 | c.2341A>G p.T781A | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs766932331, COSV54693456; called by muse, mutect2, varscan2
- PLEKHA5 | c.2826G>T p.R942S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); catalogued as COSV54693473; called by muse, mutect2, varscan2
- PLEKHG7 | c.530+7A>G | Splice Region (SNP) | VAF 83/337 reads (25%) | catalogued as COSV101188871; called by muse, varscan2
- PLEKHM3 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV66815333; called by muse, varscan2
- PLIN3 | c.1297A>G p.K433E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs768566079, COSV55733896; called by muse, varscan2
- PLPPR5 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV54168526; called by muse, mutect2, varscan2
- PLXNA3 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1557206743, COSV63753059; called by muse, mutect2, varscan2
- PLXND1 | c.3078-3del | Splice Region (DEL) | VAF 15/33 reads (45%) | catalogued as rs1278682279; called by mutect2, pindel, varscan2
- PNCK | c.959A>T p.E320V (on ENST00000340888 / NM_001366975.1; = p.E403V on NM_001039582.3) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV61742435; called by muse, mutect2, varscan2
948 further variants in this file (545 protein-altering or splice-affecting, 372 silent, 31 other) are not listed here.
